Somatic mutation profile of tumor specimen TCGA-XM-A8RF-01A (aliquot TCGA-XM-A8RF-01A-11D-A423-09) from TCGA case TCGA-XM-A8RF, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 84.6 years (30,893 days).
Specimen TCGA-XM-A8RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6a63519-4df8-4d0b-83e7-23f29af28ae3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RF-10A (Blood Derived Normal), aliquot TCGA-XM-A8RF-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d416e4-c6b5-46f8-8fbd-aedbf549675d

The open-access MAF lists 27 somatic variants for this specimen: 26 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 20, Nonsense Mutation 2, Splice Site 2, Translation Start Site 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 256/1009 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- MAP2K1 | c.159T>G p.F53L | Missense Mutation (SNP) | VAF 37/58 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1057519908, COSV61068395, COSV61071940; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL133500.1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.26); catalogued as rs1310006723, COSV55744332; called by muse, mutect2, varscan2
- AMDHD2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs776424465; called by muse, varscan2
- CCDC22 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs201021614, COSV66051272; called by muse, mutect2, varscan2
- CTPS2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.322); catalogued as rs761102007, COSV63723715; called by muse, mutect2, varscan2
- DNAH8 | c.12640G>A p.G4214R | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544464; called by muse, mutect2
- KRT26 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1055802305; called by muse, mutect2, varscan2
- LILRB4 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.923); catalogued as COSV54403208; called by muse, mutect2
- PAX7 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as rs370742910; called by muse, mutect2, varscan2
- PPFIBP1 | c.2116C>T p.Q706* (on ENST00000318304 / NM_177444.3; = p.Q700* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 59/157 reads (38%) | catalogued as rs866101596; called by muse, mutect2, varscan2
- RIPOR1 | c.1025C>T p.T342I (on ENST00000379312 / NM_001193522.2; = p.T338I on NM_024519.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV50232550; called by muse, mutect2, varscan2
- UBR4 | c.8143A>G p.T2715A | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.931); catalogued as COSV100921362; called by muse, mutect2, varscan2
- ZNF438 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756547264; called by muse, mutect2, varscan2
- ABCD4 | c.735_736dup p.H246Rfs*3 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- ADAM23 | c.2174G>A p.C725Y | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK6 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DMD | c.3164A>C p.N1055T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- H2BC11 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); called by muse, mutect2
- KHDRBS3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NAF1 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- RLN3 | c.191-1G>A p.X64_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- RYR2 | c.5552T>A p.F1851Y | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SCARB2 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- SETMAR | c.2003T>G p.L668R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SLC22A17 | n.1553+2T>G | Splice Site (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- RALGPS1 | c.397C>T p.L133= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as rs150464808; called by muse, mutect2, varscan2
